Somatic mutation profile of tumor specimen MP2PRT-PARKJI-TMP1-A (aliquot MP2PRT-PARKJI-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARKJI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.8 years (2,831 days).
Specimen MP2PRT-PARKJI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51f33b68-521e-40c9-914d-fc1ae75361b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARKJI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARKJI-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/829fd962-79ba-4831-8405-2f9a8e9e879b

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 10, Silent 6, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 175/454 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.329A>C p.E110A | Missense Mutation (SNP) | VAF 111/250 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as rs397507519, CM044251, COSV61012782; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADSS1 | c.1147G>A p.G383R | Missense Mutation (SNP) | VAF 111/512 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs779161094, COSV100272364; called by muse, mutect2, varscan2
- NRN1 | c.57G>A p.A19= | Splice Region (SNP) | VAF 174/522 reads (33%) | catalogued as COSV55205696; called by muse, mutect2, varscan2
- PLEKHA5 | c.3133G>A p.A1045T | Missense Mutation (SNP) | VAF 131/330 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748283572, COSV54713066; called by muse, mutect2, varscan2
- POLE | c.6587C>T p.S2196F | Missense Mutation (SNP) | VAF 30/728 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.163); catalogued as COSV57681177; called by muse, mutect2
- CRYBA2 | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 328/747 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- IGLV8-61 | c.367dup p.*123Ffs*? | Frame Shift Ins (INS) | VAF 70/147 reads (48%) | called by pindel, varscan2
- PTPRS | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 255/589 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- STON2 | c.1982T>C p.F661S (on ENST00000649389 / NM_001366849.2; = p.F604S on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 242/828 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF11L12 | c.486G>T p.M162I | Missense Mutation (SNP) | VAF 118/283 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TNFRSF13C | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 270/579 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHRNB2 | c.660G>A p.T220= | Silent (SNP) | VAF 286/946 reads (30%) | catalogued as rs539974140, COSV63808638; called by muse, mutect2, varscan2
- MAN1A1 | c.1362C>T p.S454= | Silent (SNP) | VAF 119/443 reads (27%) | catalogued as rs781162578; called by muse, mutect2, varscan2
- NPAS3 | c.2496G>A p.A832= (on ENST00000356141 / NM_001164749.2; = p.A800= on NM_022123.3) | Silent (SNP) | VAF 312/1133 reads (28%) | catalogued as COSV100640237; called by muse, varscan2
- NYX | c.678C>T p.F226= | Silent (SNP) | VAF 558/1181 reads (47%) | called by muse, mutect2, varscan2
- SH3BGRL2 | c.165G>A p.P55= | Silent (SNP) | VAF 237/788 reads (30%) | catalogued as rs142224954; called by muse, mutect2, varscan2
- ZNF483 | c.261G>A p.T87= | Silent (SNP) | VAF 229/549 reads (42%) | catalogued as rs1482665617, COSV58515276; called by muse, mutect2, varscan2
